TCGA case TCGA-SP-A6QH — Pheochromocytoma and Paraganglioma (TCGA-PCPG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Paragangliomas and Glomus Tumors; Primary site: Adrenal gland; Tissue source site: University Health Network. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4afdc661-7127-4c2e-9b66-4b0313772280

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 35 years; Vital status: Alive.

Diagnoses (4)
1. Pheochromocytoma, NOS (the primary disease): ICD-O-3 morphology code: 8700/0; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Site of resection or biopsy: Adrenal gland, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 35.3 years (12,876 days); Year of diagnosis: 2008; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No; Days to last follow up: 2,203 days (6.0 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Haemangioblastoma: ICD-O-3 morphology code: 9161/1; Tissue or organ of origin: Vertebral column; Classification of tumor: Prior primary; Age at diagnosis: 34.5 years (12,607 days); Days to diagnosis: -269 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -269 days; Treatment anatomic sites: Cervical Spine.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Paraganglioma, NOS: ICD-O-3 morphology code: 8680/1; Tissue or organ of origin: Retroperitoneum; Classification of tumor: Synchronous primary; Age at diagnosis: 35.2 years (12,866 days); Days to diagnosis: -10 days.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -10 days; Treatment anatomic sites: Lymph Node(s) Paraaortic.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Carcinoid tumor, NOS: ICD-O-3 morphology code: 8240/3; Tissue or organ of origin: Pancreas, NOS; Classification of tumor: Synchronous primary; Age at diagnosis: 35.2 years (12,866 days); Days to diagnosis: -10 days; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA.
   Treatment given: Treatment type: Whipple; Days to treatment start: -10 days; Treatment anatomic sites: Pancreas.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 0 (prior to diagnosis): History of tumor: Yes; History of tumor type: Phenochromocytoma or Paraganglioma.
- Days to follow up: 1,857 days (5.1 years); Disease response: Tumor Free.
- Days to follow up: 2,203 days (6.0 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SP-A6QH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 110 mg.
  Slide TCGA-SP-A6QH-01A-02-TS2: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-SP-A6QH-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SP-A6QH-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 80 mg.
  Slide TCGA-SP-A6QH-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History pheo or para include benign: Yes; History pheo or para anatomic site: retroperitoneal; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Primary pathology: Related tumors outside adrenal glands: Multiple tumors outside the adrenal glands; Histologic diagnosis: Pheochromocytoma; Disease detected on screening: No; Ct scan preop results: Yes; Lymph nodes examined: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy; Other malignancy histological type: Paraganglioma.
- Other malignancy form 1, Surgery: Other malignancy surgery type: para-aortic lymph node disection.
- Other malignancy form 2: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Pancreas; Other malignancy histological type: Well-differentiated neuroendocrine carcinoma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Whipple resection.
- Other malignancy form 3: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Spine; Other malignancy histological type: hemangioblastoma.
- Other malignancy form 3, Surgery: Other malignancy surgery type: c4-c5 tumor resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,203 days; disease-specific survival: no event (censored), 2,203 days; disease-free interval: no event (censored), 2,203 days; progression-free interval: no event (censored), 2,203 days.
